Gene-level copy-number profile of tumor specimen C3N-01842-01 from CPTAC case C3N-01842, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G2; Age at diagnosis: 69.9 years (25,527 days).
Specimen C3N-01842-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 18980f86-d190-4209-ab72-ae4faf1cd377.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-01842-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,742 have no estimate.
https://portal.gdc.cancer.gov/files/2fc387a5-dd74-4d80-b8c2-140241b32929

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 523; copy number 1: 7; copy number 2: 13,654; copy number 3: 7,613; copy number 4: 26,387; copy number 5: 1,767; copy number 6: 5,439; copy number 7: 1,518; copy number 8: 409; copy number 9: 316; copy number 10: 679; copy number 11: 238; copy number 12: 248; copy number 13: 40; copy number 14: 12; copy number 15: 6; copy number 16: 8; copy number 18: 4; copy number 26: 13.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:180,967,189–181,006,727, 4 genes: AC091874.2, AC091874.1, ARPP19P1, BTNL3.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,564 genes in 26 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–24,271,863, 377 genes, copy number 10 (within-gene range 7–10) (broad region; genes not listed).
- chr5:24,487,100–25,190,956, 11 genes, copy number 10 (within-gene range 6–10): CDH10, AC091885.2, AC091885.1, AC091893.1, AC106821.2, BTG4P1, SNORD29, LINC02239, AC106821.1, Y_RNA, LINC02228.
- chr5:25,188,059–25,188,778, 1 gene, copy number 10: AC099499.2.
- chr5:29,795,938–29,983,114, 5 genes, copy number 10: AC108082.1, AC010374.2, AC010374.1, RN7SKP207, AC018765.1.
- chr5:44,742,420–45,895,970, 9 genes, copy number 10: MRPS30-DT, AC093297.1, MRPS30, AC093297.2, AC114954.1, HCN1, AC117529.2, AC117529.1, AC122694.1.
- chr6:1,312,098–2,640,001, 19 genes, copy number 9–14: FOXQ1, LINC01394, AL034346.1, FOXF2, MIR6720, RN7SL352P, AL512329.1, AL512329.2, FOXCUT, FOXC1, GMDS, AL035693.1, GMDS-DT, HMGN2P28, AL031768.2, AL031768.1, AL359852.1, LINC02521, LINC01600.
- chr6:3,693,923–4,157,385, 21 genes, copy number 9: AL033523.2, PXDC1, AL391422.4, AL391422.1, AL391422.3, AL391422.2, FAM50B, AL590004.3, AL590004.2, AL590004.1, TDGF1P4, GLRX3P2, AL138831.3, AL138831.2, AL138831.1, PRPF4B, FAM217A, C6orf201, ECI2, AL136309.3, ECI2-DT.
- chr6:5,003,774–5,089,487, 4 genes, copy number 9 (within-gene range 5–9): LYRM4-AS1, AL359643.2, AL139094.1, PPP1R3G.
- chr6:5,261,044–12,585,404, 122 genes, copy number 9 (broad region; genes not listed).
- chr6:17,737,458–18,122,677, 4 genes, copy number 9–13: Y_RNA, KIF13A, AL023807.1, NHLRC1.
- chr6:19,290,319–21,602,383, 27 genes, copy number 10–18: AL357052.1, LNC-LBCS, RPL5P20, RNA5SP205, KRT18P38, UQCRFS1P3, RNU6-801P, ID4, AL008627.1, MBOAT1, AL158198.1, AL158198.2, E2F3, RN7SL128P, E2F3-IT1, RNU6-141P, Y_RNA, CDKAL1, AL035090.1, AL513188.1, RNU6-150P, AL031767.1, LINC00581, AL512380.1, AL512380.2, SOX4, BOLA2P3.
- chr6:29,896,654–30,327,382, 36 genes, copy number 10–15 (within-gene range 5–15): HLA-T, DDX39BP1, MCCD1P1, HCG4B, HLA-K, HLA-U, HLA-A, AL671277.1, HLA-W, MICD, HCG9, DDX39BP2, MCCD1P2, ZNRD1ASP, HLA-J, AL671277.2, ETF1P1, AL669914.3, AL669914.2, POLR1H, AL669914.4, PPP1R11, RNF39, TRIM31, TRIM31-AS1, AL669914.1, TRIM40, TRIM10, TRIM15, TRIM26, PAIP1P1, HCG17, TRIM26BP, HLA-L, AL662795.2, HCG18.
- chr6:30,798,654–31,180,731, 27 genes, copy number 10: LINC00243, LINC02570, RN7SKP186, DDR1-DT, DDR1, MIR4640, GTF2H4, AL669830.1, VARS2, SFTA2, Y_RNA, MUCL3, HCG21, NAPGP2, MUC21, MUC22, HCG22, RNU6-1133P, C6orf15, PSORS1C1, CDSN, PSORS1C2, POLR2LP1, CCHCR1, TCF19, POU5F1, PSORS1C3.
- chr6:150,326,623–150,510,300, 4 genes, copy number 10: RNU4-7P, IYD, SSR1P1, AL451061.1.
- chr8:7,190,901–7,191,563, 1 gene, copy number 9: RPS3AP33.
- chr10:47,908,064–47,991,877, 3 genes, copy number 16: AC245041.2, NPY4R2, AC245041.1.
- chr14:18,333,726–18,343,144, 2 genes, copy number 11: CR383658.1, RNU6-458P.
- chr17:20,008,865–20,319,026, 1 gene, copy number 16 (within-gene range 2–16): SPECC1.
- chr17:20,185,082–20,844,257, 47 genes, copy number 9–16 (within-gene range 2–16): AC004702.1, RNU6-1057P, CCDC144CP, RNU6-467P, AC008088.1, Metazoa_SRP, UPF3AP2, USP32P3, SRP68P3, AC015818.9, AC015818.10, NOS2P3, LGALS9B, TNPO1P3, YWHAEP3, KRT16P5, KRT16P3, AC015818.7, KRT17P6, KRT17P7, AC015818.6, AC015818.2, AC015818.5, TBC1D3P3, AC015818.8, AC015818.1, AC015818.3, COTL1P2, AC015818.4, CDRT15L2, ZSWIM5P2, MEIS3P2, AC087499.3, AC087499.1, AC087499.4, LINC02088, AC087499.7, AC087499.5, AC087499.6, AC087499.2, RNFT1P3, HNRNPA1P19, OLA1P2, SCDP1, AC126365.1, AC126365.2, ABHD17AP6.
- chr18:670,318–2,489,426, 27 genes, copy number 11 (within-gene range 2–11): ENOSF1, AP001178.2, YES1, AP001020.3, AP001020.1, AP001020.2, RNU1-109P, AP000894.4, BOLA2P1, AP000894.1, AP000894.3, AP000894.2, ADCYAP1, LINC01904, AP005328.1, AP000829.1, SLC25A3P3, COX6CP3, LINC00470, RN7SKP72, AP005119.1, AP005119.2, AP005262.1, AC019183.1, AP005057.1, AP005230.1, AIDAP3.
- chr18:2,847,006–4,459,458, 39 genes, copy number 10: EMILIN2, LPIN2, AP000919.3, CHORDC1P4, AP000919.1, AP000919.2, SNRPCP4, AP005431.1, SNORA70, MYOM1, RNU7-25P, AP005329.2, AP005329.3, MYL12A, AP005329.1, MYL12B, AP001025.1, LINC01895, RPL31P59, IGLJCOR18, RPL21P127, TGIF1, BOD1P1, GAPLINC, DLGAP1, RN7SL39P, AP002472.1, DLGAP1-AS1, DLGAP1-AS2, AP002478.1, AP002478.2, DLGAP1-AS3, MIR6718, RNU6-831P, DLGAP1-AS4, GAPDHP66, DLGAP1-AS5, AP005208.1, ELOCP27.
- chr19:27,638,483–33,927,625, 127 genes, copy number 9–12 (broad region; genes not listed).
- chr19:34,254,552–43,269,530, 482 genes, copy number 10–12 (broad region; genes not listed).
- chr19:44,207,547–45,070,956, 46 genes, copy number 10–26: ZNF227, ZNF235, AC138470.1, ZNF233, AC138473.1, NDUFA3P1, ZNF112, AC245748.1, ZNF285, AC245748.2, ZNF229, ZNF285B, ZNF180, CEACAM20, AC245748.3, CEACAM22P, AC243964.1, IGSF23, AC243964.3, PVR, MIR4531, CEACAM19, AC243964.4, CEACAM16, AC243964.2, BCL3, MIR8085, SNORA70, AC092066.1, CBLC, BCAM, NECTIN2, AC011481.2, TOMM40, APOE, AC011481.3, APOC1, APOC1P1, APOC4, APOC4-APOC2, APOC2, AC011481.1, CLPTM1, RELB, CLASRP, RNU6-611P.
- chr21:21,566,763–26,573,286, 69 genes, copy number 11–13 (broad region; genes not listed).
- chr21:29,536,933–31,063,168, 53 genes, copy number 11 (within-gene range 3–11): GRIK1, AP000238.1, GRIK1-AS1, AF096876.1, CLDN17, LINC00307, CLDN8, RPL8P2, KRTAP24-1, KRTAP25-1, KRTAP26-1, KRTAP27-1, KRTAP23-1, KRTAP13-6P, KRTAP13-2, MIR4327, KRTAP13-1, KRTAP13-3, KRTAP13-4, KRTAP13-5P, KRTAP15-1, KRTAP19-1, KRTAP19-2, KRTAP19-3, KRTAP19-4, KRTAP19-5, KRTAP19-9P, KRTAP19-10P, AP000567.1, KRTAP19-11P, KRTAP19-6, KRTAP19-7, KRTAP22-2, KRTAP6-3, KRTAP6-2, KRTAP22-1, KRTAP6-1, KRTAP20-1, KRTAP20-4, KRTAP20-2, KRTAP20-3, KRTAP21-3, KRTAP21-4P, KRTAP21-2, KRTAP21-1, AP000244.1, KRTAP8-2P, KRTAP8-3P, KRTAP8-1, KRTAP7-1, KRTAP11-1, KRTAP19-8, UBE3AP2.

Autosomal genes at a single copy (total copy number 1): 2. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
